TCGA case TCGA-DY-A1H8 — Rectum Adenocarcinoma (TCGA-READ)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum; Tissue source site: University Of Michigan. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c2395f04-e248-4091-855d-802b1b871f29

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 77 years; Vital status: Dead; Days to death: 992 days (2.7 years).

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C20; Tissue or organ of origin: Rectum, NOS; Site of resection or biopsy: Rectum, NOS; Classification of tumor: primary; Age at diagnosis: 77.9 years (28,459 days); Year of diagnosis: 2000; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 7.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 992.

Molecular and laboratory tests
- KRAS mutation, nos: Positive; Mutation codon: 12.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 40 kg; Height: 160 cm; BMI: 15.6.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DY-A1H8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 180 mg.
  Slide TCGA-DY-A1H8-01A-02-TSB: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DY-A1H8-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Rectal Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Lymph nodes examined: Yes; Loci tested count: 0; Loci abnormal count: 0; KRAS gene analysis indicator: Yes; KRAS mutation found: Yes; BRAF gene analysis indicator: No.
- Follow-up form: New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 992 days; disease-specific survival: event status not recorded, 992 days; progression-free interval: no event (censored), 992 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DY-A1H8-01A-21D-A151-01): tumor purity 0.89, ploidy 2.13, whole-genome doublings 0.
